TCGA case TCGA-A2-A0T7 — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Walter Reed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/43d5632e-7272-4aad-9496-7f5a99671223

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 51.4 years (18,756 days); Year of diagnosis: 2009; Method of diagnosis: Core Biopsy; AJCC pathologic T: T2; AJCC pathologic N: N0 (i+); AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Right Upper Inner.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 2; Micrometastasis present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Adjuvant; Days to treatment start: 117 days; Days to treatment end: 145 days; Number of cycles: 3; Prescribed dose: 1100; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 117 days; Days to treatment end: 145 days; Number of cycles: 3; Prescribed dose: 110; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 159 days; Days to treatment end: 243 days; Number of cycles: 12; Prescribed dose: 145; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Treatment intent type: Adjuvant; Days to treatment start: 365 days (1.0 years); Treatment outcome: Treatment Ongoing; Prescribed dose: 20; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Involved; Treatment anatomic sites: Breast.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: Re-Excision; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 397 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 631 days (1.7 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (IHC): Negative; Staining intensity value: 1+.
- ESR1 (IHC): Positive; Staining intensity value: 2+; Test value range: 90-99%.
- PGR (IHC): Positive; Staining intensity value: 2+; Test value range: 70-79%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A2-A0T7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 990 mg.
  Slide TCGA-A2-A0T7-01A-02-BSB: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 20.
  Slide TCGA-A2-A0T7-01A-02-TSB: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 20.
- Sample TCGA-A2-A0T7-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A2-A0T7-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Axillary staging method: Sentinel node biopsy alone; Surgical procedure first: Modified Radical Mastectomy; Surgery for positive margins other: Skin excision; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Micromet detection by IHC: Yes; Er IHC score: 2+; Her2 IHC score: 1+; Method initial path diagnosis: Core needle biopsy; Lymph nodes examined IHC count: 1; Prospective collection: No; Retrospective collection: Yes.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right Upper Inner Quadrant.
- Follow-up form: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Adriamycin.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 3; Pharmaceutical therapy drug name: Taxol.
- Drug treatment 3: Regimen number: 4.
- Drug treatment 3, Route of administrations: Route of administration: PO.
- Drug treatment 4: Regimen number: 2; Pharmaceutical therapy drug name: Cytoxan.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 631 days; disease-specific survival: no event (censored), 631 days; disease-free interval: no event (censored), 631 days; progression-free interval: no event (censored), 631 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A2-A0T7-01A-21D-A087-01): tumor purity 0.49, ploidy 1.97, whole-genome doublings 0.
